Somatic mutation profile of tumor specimen 0DVR8D from CCDI case PBCNBP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.1 years (6,230 days).
Specimen 0DVR8D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88f34627-ae35-411f-a048-4f7a365a081f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVR5V (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5952a88-acbe-4713-bba2-b3be5d3c91a6

The open-access MAF lists 49 somatic variants for this specimen: 30 protein-altering or splice-affecting, 13 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 13, Intron 3, Nonsense Mutation 2, Splice Region 1, 5'Flank 1, Frame Shift Ins 1, 3'UTR 1, Splice Site 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AXDND1 | c.2091C>T p.H697= | Splice Region (SNP) | VAF 87/413 reads (21%) | catalogued as rs767651503, COSV62648840; called by muse, mutect2, varscan2
- CPAMD8 | c.3404G>A p.R1135Q (on ENST00000651564; = p.R1088Q on NM_015692.5) | Missense Mutation (SNP) | VAF 108/355 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs61742969, COSV71595756; called by muse, mutect2, varscan2
- DNAH2 | c.2489G>A p.R830H | Missense Mutation (SNP) | VAF 22/325 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs765692580, COSV101208998, COSV66726799; called by muse, mutect2
- ENTHD1 | c.1475G>A p.G492E | Missense Mutation (SNP) | VAF 29/322 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57321204; called by muse, mutect2
- GAB4 | c.1687C>T p.R563W | Missense Mutation (SNP) | VAF 28/559 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1404705985, COSV68754354; called by muse, mutect2
- GEMIN4 | c.2503C>G p.L835V | Missense Mutation (SNP) | VAF 112/337 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.553); catalogued as rs766616046; called by muse, mutect2, varscan2
- GRM1 | c.2050C>T p.R684C | Missense Mutation (SNP) | VAF 45/360 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763886921, COSV51110227; called by muse, varscan2
- ITGB2 | c.2351C>T p.T784M (on ENST00000302347; = p.T760M on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/311 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs542061261; called by muse, mutect2, varscan2
- MVK | c.393del p.I131Mfs*2 | Frame Shift Del (DEL) | VAF 44/428 reads (10%) | catalogued as COSV57331914; called by mutect2, pindel, varscan2
- MYLK3 | c.1324G>T p.A442S | Missense Mutation (SNP) | VAF 39/300 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as rs768408009; called by muse, mutect2, varscan2
- MYO3A | c.77C>T p.T26I | Missense Mutation (SNP) | VAF 35/307 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs749551065; called by muse, mutect2, varscan2
- PDE9A | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs201811895; called by muse, mutect2
- RRP8 | c.841C>T p.H281Y | Missense Mutation (SNP) | VAF 75/347 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1386151963; called by muse, mutect2, varscan2
- SPATA13 | c.1811C>T p.P604L | Missense Mutation (SNP) | VAF 47/556 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.052); catalogued as rs766100648; called by muse, mutect2
- TUBGCP6 | c.3555G>A p.W1185* | Nonsense Mutation (SNP) | VAF 25/241 reads (10%) | catalogued as rs1429923697; called by muse, mutect2, varscan2
- UIMC1 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 62/281 reads (22%) | catalogued as rs867346051; called by muse, mutect2, varscan2
- USP19 | c.3610C>A p.R1204S | Missense Mutation (SNP) | VAF 14/450 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as COSV67350023; called by muse, mutect2
- ZNF600 | c.1004G>C p.C335S | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs756088170; called by muse, mutect2, varscan2
- ZNF778 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 116/436 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as rs1040492474, COSV100124249; called by muse, mutect2, varscan2
- ADD3 | c.450G>T p.L150F | Missense Mutation (SNP) | VAF 54/402 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP10B | c.3895T>C p.Y1299H | Missense Mutation (SNP) | VAF 18/544 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CEACAM5 | c.1688G>A p.R563K | Missense Mutation (SNP) | VAF 22/421 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2
- EOMES | c.1012G>T p.G338C | Missense Mutation (SNP) | VAF 49/416 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ISM2 | c.1209C>A p.S403R (on ENST00000342219 / NM_199296.3; = p.A288D on NM_182509.4) | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); called by muse, mutect2
- MXD3 | c.364dup p.R122Kfs*41 | Frame Shift Ins (INS) | VAF 49/389 reads (13%) | called by mutect2, pindel, varscan2
- PRDM8 | c.1207A>T p.T403S | Missense Mutation (SNP) | VAF 29/237 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SELP | c.712G>A p.G238R | Missense Mutation (SNP) | VAF 49/529 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2
- SPO11 | c.362T>C p.I121T | Missense Mutation (SNP) | VAF 21/277 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.225); called by muse, mutect2
- STK33 | c.1061-1G>A p.X354_splice | Splice Site (SNP) | VAF 21/248 reads (8%) | called by muse, mutect2
- TDRD6 | c.4525G>C p.V1509L | Missense Mutation (SNP) | VAF 291/558 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BEND7 | c.765A>G p.S255= | Silent (SNP) | VAF 24/444 reads (5%) | called by muse, mutect2
- BMPR1A | c.1209C>T p.G403= | Silent (SNP) | VAF 15/401 reads (4%) | called by muse, mutect2
- CAMSAP3 | c.3645C>T p.P1215= | Silent (SNP) | VAF 19/299 reads (6%) | catalogued as COSV50333955; called by muse, mutect2
- CLASRP | c.1101G>A p.P367= | Silent (SNP) | VAF 51/338 reads (15%) | catalogued as rs752484206, COSV99673420; called by muse, mutect2, varscan2
- CRB2 | c.1683G>A p.P561= | Silent (SNP) | VAF 30/476 reads (6%) | catalogued as rs763374681; called by muse, mutect2
- DLG5 | c.729C>T p.D243= | Silent (SNP) | VAF 49/359 reads (14%) | catalogued as rs772203646; called by muse, mutect2, varscan2
- EFEMP1 | c.1353C>T p.L451= | Silent (SNP) | VAF 53/343 reads (15%) | catalogued as rs1399879099, COSV62617719; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KRT82 | c.1497C>T p.S499= | Silent (SNP) | VAF 28/216 reads (13%) | called by muse, mutect2, varscan2
- OR10T2 | c.201T>C p.L67= | Silent (SNP) | VAF 50/543 reads (9%) | called by muse, mutect2
- PCDH7 | c.216C>G p.S72= | Silent (SNP) | VAF 35/375 reads (9%) | catalogued as COSV62336590; called by muse, mutect2
- RASSF6 | c.1062G>A p.L354= (on ENST00000342081 / NM_201431.2; = p.L322= on NM_177532.5) | Silent (SNP) | VAF 30/348 reads (9%) | catalogued as rs1359643863, COSV56721527; called by muse, mutect2
- URB1 | c.486G>A p.P162= | Silent (SNP) | VAF 26/539 reads (5%) | catalogued as rs1398978091; called by muse, mutect2
- XPC | c.1023G>A p.A341= | Silent (SNP) | VAF 93/372 reads (25%) | catalogued as rs370847346; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GP6 | c.35-66C>T | Intron (SNP) | VAF 28/108 reads (26%) | catalogued as rs558709117; called by muse, mutect2, varscan2
- KLRK1 | c.278-78A>G | Intron (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- MIR205 | chr1:209430481 G>C | 5'Flank (SNP) | VAF 64/344 reads (19%) | called by muse, mutect2, varscan2
- NHSL1 | c.203-2959T>A | Intron (SNP) | VAF 26/163 reads (16%) | called by muse, mutect2, varscan2
- PFKL | c.-1C>G | 5'UTR (SNP) | VAF 15/135 reads (11%) | called by muse, varscan2
- SPOCK2 | c.*3G>A | 3'UTR (SNP) | VAF 24/198 reads (12%) | catalogued as rs780585961, COSV58035943; called by muse, mutect2, varscan2
